Somatic mutation profile of tumor specimen 0DKIII from CCDI case PBBYJY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Large cell medulloblastoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 10.8 years (3,928 days).
Specimen 0DKIII: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2940427e-4110-4fbc-8abf-fa9f790da4e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKIHW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7dc3c5aa-e163-4d01-8cb3-6f1bd3847988

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Splice Region 1, Intron 1, Frame Shift Ins 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACB | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 112/364 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99060920; called by muse, mutect2, varscan2
- APLP2 | c.2233A>T p.M745L | Missense Mutation (SNP) | VAF 19/607 reads (3%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as rs1382262423; called by muse, mutect2
- C3AR1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 174/538 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756745490, COSV50817573; called by muse, mutect2, varscan2
- GULP1 | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 59/301 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs768506343; called by muse, mutect2, varscan2
- HIPK2 | c.1620C>T p.H540= | Splice Region (SNP) | VAF 239/640 reads (37%) | catalogued as rs773317560; called by muse, mutect2, varscan2
- IL1RL2 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 208/653 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.709); catalogued as rs866058726, COSV51812942, COSV51816541; called by muse, mutect2, varscan2
- MTF1 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 128/412 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1400769524; called by muse, mutect2, varscan2
- RNGTT | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 176/396 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.156); catalogued as rs1296595962, COSV55650219; called by muse, mutect2, varscan2
- TEX55 | c.1049C>A p.A350E | Missense Mutation (SNP) | VAF 230/528 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.54); catalogued as rs756506680; called by muse, mutect2, varscan2
- TONSL | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 144/480 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as COSV68047961; called by muse, mutect2, varscan2
- TTN | c.70231C>T p.R23411C (on ENST00000591111; = p.R15987C on NM_003319.4) | Missense Mutation (SNP) | VAF 26/516 reads (5%) | PolyPhen probably damaging (0.917); catalogued as rs1303893206, COSV59867929, COSV60214849; called by muse, mutect2
- CHST7 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.253); called by muse, mutect2
- MRC1 | c.4019G>T p.G1340V | Missense Mutation (SNP) | VAF 27/562 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NLRC5 | c.5321+2T>A p.X1774_splice | Splice Site (SNP) | VAF 114/430 reads (27%) | called by muse, mutect2, varscan2
- UACA | c.2667dup p.F890Ifs*2 | Frame Shift Ins (INS) | VAF 86/327 reads (26%) | called by mutect2, varscan2
- AQP12A | c.82C>T p.L28= | Silent (SNP) | VAF 121/468 reads (26%) | catalogued as rs749783111; called by muse, mutect2, varscan2
- CAVIN2 | c.891C>T p.F297= | Silent (SNP) | VAF 121/370 reads (33%) | catalogued as COSV100414201; called by muse, mutect2, varscan2
- DGLUCY | c.1476G>A p.E492= | Silent (SNP) | VAF 24/662 reads (4%) | called by muse, mutect2
- HEG1 | c.1749C>T p.S583= | Silent (SNP) | VAF 23/668 reads (3%) | called by muse, mutect2
- SMG8 | c.1431G>A p.K477= | Silent (SNP) | VAF 142/1274 reads (11%) | catalogued as rs1158105802; called by muse, mutect2, varscan2
- ICAM4 | c.*186dup | 3'UTR (INS) | VAF 5/14 reads (36%) | called by mutect2, varscan2
- RPS20 | c.4-41C>G | Intron (SNP) | VAF 42/203 reads (21%) | called by muse, mutect2, varscan2
